Surgical pathology report (de-identified scan), TCGA case TCGA-75-7025, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-75-7025-01A (Primary Tumor).

[page 1 of 4]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details

Sample Number	Sample Type
	BUFFY
	TUMOUR

[page 2 of 4]
					Histology and staging			
Sample Preparation	Site of Tissue	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)
FF	LLL Lung					0	13 RESECT	LUL
FF						0	13 RESECT	LUL

[page 3 of 4]
Tumour Size (cm)	Histology	Grade/ Differentiation	Pathologic al T	Pathologic al N	Clinical M	VALCSG Stage	Histology Comments	Slide URL
3.4		3 I	T2,NOS	N0	M0			
3.4		3 I	T2,NOS	N0	M0			

[page 4 of 4]
[REDACTED]

Source: NCI Genomic Data Commons file 32a544c9-e1fd-4e5b-aa37-50cf5aaa66a9 (TCGA-75-7025.6D05110B-1A5F-4002-B140-00A36C5C102B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).